Gene-level copy-number profile of tumor specimen REBC-ADKR-TTP1-A from REBC case REBC-ADKR, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADKR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file faf36d81-8b7b-4fd7-a56a-05639554ac87.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADKR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/527e2e4a-fa9b-4071-8131-79461803c3de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 201; copy number 2: 58,119; copy number 3: 46; copy number 4: 9; copy number 5: 16; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:72,996,803–73,069,198, 3 genes (within-gene range 0–2): PPP4R2, RNU7-19P, EBLN2.
- chr6:82,263,996–82,264,974, 1 gene: AL121977.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,391,707, 5 genes, copy number 5: AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2.
- chr2:197,569–209,892, 1 gene, copy number 7: AC079779.1.
- chr19:54,379,489–54,439,544, 6 genes, copy number 5: AC245884.4, TTYH1, AC245884.1, AC245884.9, AC245884.10, AC245884.8.
- chr21:44,350,163–44,455,284, 5 genes, copy number 5: TRPM2, TRPM2-AS, AP001065.2, AP001065.1, LRRC3-DT.

Autosomal genes at a single copy (total copy number 1): 201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
